TCGA case TCGA-AA-3845 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc02f801-081b-489b-87cb-d275c70299d5

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 86 years; Vital status: Dead; Days to death: 0 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 86.5 years (31,593 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 12; Lymphatic invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-AA-3845-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 3; Percent stromal cells: 8.
  Slide TCGA-AA-3845-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 8.
- Sample TCGA-AA-3845-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3845-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 0 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 0 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3845-01A-01D-1018-01): tumor purity 0.59, ploidy 2.09, whole-genome doublings 0.
